Gene-level copy-number profile of tumor specimen HCM-CSHL-0462-D05-31B from HCMI case HCM-CSHL-0462-D05, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Intraductal carcinoma, noninfiltrating, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 49.1 years (17,939 days).
Specimen HCM-CSHL-0462-D05-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8406e6df-abe9-46cb-a5d3-0b40b0a07b2a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0462-D05-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/5369aeb6-f992-4e00-b6c9-1ebcf43b5fe2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 3,306; copy number 2: 52,061; copy number 3: 2,933; copy number 4: 31; copy number 5: 6; copy number 6: 1; copy number 7: 5; copy number 10: 1; copy number 23: 1; copy number 42: 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,523,648–49,523,857, 1 gene: AC119751.2.
- chr6:39,299,001–39,314,461, 1 gene: KCNK17.
- chr9:121,494,519–121,494,821, 1 gene (within-gene range 0–2): RN7SL187P.
- chr14:18,889,084–19,003,752, 8 genes: NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P.
- chr14:19,324,708–19,384,587, 3 genes (within-gene range 0–4): AL929602.1, LINC01297, GRAMD4P3.
- chr15:28,830,619–28,831,182, 1 gene (within-gene range 0–2): AC055876.6.
- chr16:46,689,643–46,931,289, 7 genes: ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,087,351–242,088,457, 1 gene, copy number 10: AC093642.2.
- chr5:135,802,985–135,803,075, 1 gene, copy number 7: MIR5692C1.
- chr9:136,779,939–136,780,218, 1 gene, copy number 5: ATP6V1G1P3.
- chr9:136,975,092–136,996,568, 5 genes, copy number 5–6: PTGDS, AL807752.7, LCNL1, PAXX, CLIC3.
- chr9:137,048,107–137,054,061, 2 genes, copy number 7 (within-gene range 7–20): ENTPD2, AL807752.4.
- chr14:19,485,336–19,489,148, 1 gene, copy number 23: MED15P6.
- chr14:105,526,583–105,530,202, 1 gene, copy number 42: TMEM121.
- chr14:105,583,731–105,588,395, 1 gene, copy number 5: IGHA2.
- chr19:1,228,287–1,238,027, 1 gene, copy number 7 (within-gene range 2–7): CBARP.
- chr19:1,275,530–1,279,244, 1 gene, copy number 7: FAM174C.

Autosomal genes at a single copy (total copy number 1): 3,156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
